CPTAC case C3N-01522 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8be8aafe-ccd7-437f-aa68-09c4bc248d1d

Demographics
Sex at birth: male; Race: white; Year of birth: 1936; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 80.4 years (29,350 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 692 days (1.9 years); Progression or recurrence: no; Days to last follow up: 692 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm (a second GDC size field records 2.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10; Margin status: Uninvolved; Sarcomatoid present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 174 days; Disease response: Tumor Free.
- Days to follow up: 692 days (1.9 years); Disease response: Complete Response.
- Days to follow up: 692 days (1.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 90 kg; Height: 171 cm; BMI: 30.78.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01522-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 500 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01522-21: Section location: Upper pole; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3N-01522-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 470 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01522-22: Section location: Upper pole; Percent tumor nuclei: 95; Percent necrosis: 5.
- Sample C3N-01522-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 510 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01522-23: Section location: Upper pole; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-01522-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 220 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-01522-31, C3N-01522-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01522-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
- Sample C3N-01522-72: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
